Somatic mutation profile of tumor specimen TCGA-A2-A4RW-01A (aliquot TCGA-A2-A4RW-01A-21D-A25Q-09) from TCGA case TCGA-A2-A4RW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.4 years (18,060 days).
Specimen TCGA-A2-A4RW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8e96608-1be5-49c1-87de-d8245111e25f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A4RW-10A (Blood Derived Normal), aliquot TCGA-A2-A4RW-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06f02f0e-c840-424d-8d91-aa378c89a8a4

The open-access MAF lists 113 somatic variants for this specimen: 89 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 22, Nonsense Mutation 6, Splice Site 3, In Frame Del 3, Intron 2, Frame Shift Del 2, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.2776C>A p.H926N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV60912522, COSV60917542; called by muse, mutect2, varscan2
- ADGRB3 | c.3905G>C p.R1302T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.154); catalogued as COSV53257525, COSV53260206; called by muse, mutect2, varscan2
- AHNAK | c.13189C>T p.P4397S | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57226716; called by muse, mutect2, varscan2
- AKAP13 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV63467289; called by muse, mutect2, varscan2
- ARHGAP44 | c.569T>G p.V190G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52399938; called by muse, mutect2, varscan2
- ARHGAP9 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62724294; called by muse, mutect2, varscan2
- ARHGEF39 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as COSV58398065; called by muse, mutect2, varscan2
- ARID1A | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV61374989; called by muse, mutect2, varscan2
- BCL11B | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs748592687, COSV61735543; called by muse, mutect2, varscan2
- BORA | c.703C>G p.L235V (on ENST00000613797; = p.L160V on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64695755; called by muse, mutect2, varscan2
- BRIP1 | c.888G>C p.E296D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs876658249, COSV52006922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.4491G>A p.M1497I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV62397027, COSV62414487; called by muse, mutect2, varscan2
- CCDC136 | c.2191C>G p.Q731E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV52803951; called by muse, mutect2, varscan2
- CCDC159 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV52259014, COSV52262061; called by muse, mutect2, varscan2
- CCR6 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59475970; called by muse, mutect2, varscan2
- CELSR1 | c.8630G>A p.S2877N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV53098156; called by muse, mutect2, varscan2
- CENPE | c.6408G>C p.M2136I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs200997499, COSV54388346; called by muse, mutect2, varscan2
- CEP170 | c.1733C>G p.S578C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60513576; called by muse, mutect2, varscan2
- CFAP47 | c.2585G>A p.G862D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV52890530; called by muse, mutect2, varscan2
- CHST1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as COSV57325287; called by muse, mutect2, varscan2
- COL22A1 | c.3556-1G>T p.X1186_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV57355862; called by muse, mutect2, varscan2
- CYP3A5 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs1196672648, COSV56122643; called by muse, mutect2, varscan2
- DCAF1 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV60046093; called by muse, mutect2, varscan2
- DOCK3 | c.3856G>C p.E1286Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV56545325; called by muse, mutect2, varscan2
- DONSON | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV51679213; called by muse, mutect2, varscan2
- DOP1A | c.1365G>C p.Q455H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs763170333, COSV52716525; called by muse, mutect2, varscan2
- EPG5 | c.7484T>C p.V2495A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as COSV56354967; called by muse, mutect2, varscan2
- F5 | c.4241A>T p.D1414V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.209); catalogued as COSV63127498; called by muse, mutect2, varscan2
- F5 | c.3913C>G p.P1305A | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.265); catalogued as COSV63127506; called by muse, mutect2, varscan2
- FAM214B | c.1461C>G p.L487= | Splice Region (SNP) | VAF 11/42 reads (26%) | catalogued as COSV59717354, COSV59717364; called by muse, mutect2, varscan2
- FAM71B | c.1523A>T p.E508V | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV57230486; called by muse, mutect2, varscan2
- FATE1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as COSV64849274; called by muse, mutect2, varscan2
- FERD3L | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51762516, COSV51764115; called by muse, mutect2
- FRMPD4 | c.2917G>A p.A973T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.05); catalogued as COSV66214933, COSV66221767; called by muse, mutect2, varscan2
- GABRA3 | c.995T>G p.V332G | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64804104; called by muse, mutect2, varscan2
- GPNMB | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV51698414; called by muse, mutect2, varscan2
- HERC6 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs200315029, COSV52034372; called by muse, mutect2, varscan2
- HIVEP1 | c.6496C>G p.Q2166E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV65104441; called by muse, mutect2, varscan2
- HSD3B2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV65593896; called by muse, mutect2, varscan2
- IFITM2 | c.10A>T p.I4F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV67714970; called by muse, mutect2, varscan2
- IFNA7 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV53332131; called by muse, mutect2, varscan2
- ING5 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV57979780; called by muse, mutect2, varscan2
- INVS | c.2599C>A p.L867M | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as COSV52448484; called by muse, mutect2, varscan2
- ITPR3 | c.3928G>A p.E1310K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs766286619, COSV65413973; called by muse, mutect2, varscan2
- KIF7 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV67999133; called by muse, mutect2, varscan2
- KRT34 | c.1310G>C p.*437Sext*14 | Nonstop Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV67450525; called by muse, mutect2, varscan2
- LAMA5 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV53370245; called by muse, mutect2, varscan2
- LGR5 | c.2579A>G p.Q860R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57005582, COSV57009010; called by muse, mutect2, varscan2
- LRRK1 | c.3976A>T p.S1326C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52624239; called by muse, mutect2
- MAP3K15 | c.3551G>C p.R1184T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV58836839; called by muse, mutect2, varscan2
- MARCHF3 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV58039696; called by muse, mutect2, varscan2
- MYO3A | c.4651C>T p.P1551S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as COSV56327579; called by muse, mutect2, varscan2
- NLRP12 | c.2255G>A p.C752Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1212259828, COSV60753523; called by muse, mutect2, varscan2
- NOX1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV54196295; called by muse, mutect2, varscan2
- PABPC4 | c.110T>A p.V37E | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65724249; called by muse, mutect2, varscan2
- PDHA2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.531); catalogued as rs1281704703, COSV54779764; called by muse, mutect2, varscan2
- PEX13 | c.374G>C p.S125T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54371351; called by muse, mutect2, varscan2
- PHF3 | c.3970C>T p.H1324Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV50335738; called by muse, mutect2, varscan2
- PPFIBP1 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV57297625; called by muse, mutect2, varscan2
- PSG2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV61546291; called by muse, mutect2, varscan2
- PSMC3 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV54082496; called by muse, mutect2, varscan2
- RASGRF1 | c.3455C>T p.S1152F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV60213272; called by muse, mutect2, varscan2
- RIOK3 | c.1258T>C p.W420R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59774751; called by muse, mutect2, varscan2
- SAMD14 | c.191C>G p.S64W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV53311001; called by muse, mutect2, varscan2
- SEL1L2 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV53152833, COSV53156675; called by muse, mutect2, varscan2
- SH3BP5 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs757656126, COSV53746205; called by muse, mutect2, varscan2
- SH3D19 | c.1747A>G p.I583V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.685); catalogued as COSV58793358; called by muse, mutect2
- STOX1 | c.1961C>G p.S654C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs1314197613; called by muse, mutect2
- TEDC2 | c.196+1G>C p.X66_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV53542599; called by muse, mutect2, varscan2
- TEX14 | c.3887C>T p.S1296F (on ENST00000240361 / NM_001201457.2; = p.S1250F on NM_031272.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); catalogued as COSV53621687; called by muse, mutect2, varscan2
- TIAM1 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV54570448; called by muse, mutect2, varscan2
- TMEM216 | c.343C>T p.R115C (on ENST00000515837 / NM_001173990.3; = p.R54C on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs774225426, COSV58426605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TOGARAM1 | c.3484G>C p.D1162H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV63894485; called by muse, mutect2, varscan2
- TPST1 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59180013; called by muse, mutect2, varscan2
- UBR4 | c.12940A>T p.I4314F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV64397471; called by muse, mutect2, varscan2
- YEATS2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59371546; called by muse, mutect2, varscan2
- ZFX | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV58449581; called by muse, mutect2, varscan2
- ZNF318 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58936639; called by muse, mutect2, varscan2
- CACNA1F | c.3605_3630+15del p.X1202_splice | Splice Site (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel
- CRTC3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- DOCK3 | c.3531_3558del p.E1178Ffs*4 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- FCGR1A | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MUC16 | c.5476G>T p.E1826* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- MYO1H | c.677_686delinsT p.A226_E229delinsV | In Frame Del (DEL) | VAF 15/80 reads (19%) | called by pindel, varscan2*
- NUTM2A | c.893C>G p.A298G | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PGGT1B | c.571_587del p.M191Hfs*5 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- THRA | c.410_418del p.L137_E139del | In Frame Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- ZFAND4 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF37A | c.349_357del p.P117_E119del | In Frame Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- ACSM5 | c.1167T>A p.S389= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV59374258; called by muse, mutect2, varscan2
- AIDA | c.66C>T p.F22= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs765586475, COSV60665284; called by muse, varscan2
- ARHGAP15 | c.1084C>T p.L362= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV54516863; called by muse, mutect2, varscan2
- CASP8AP2 | c.306C>T p.F102= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV52749382; called by muse, mutect2, varscan2
- CCDC180 | c.1227G>T p.L409= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1375851351, COSV63834304; called by muse, mutect2, varscan2
- COASY | c.99G>A p.V33= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV55900181; called by muse, mutect2, varscan2
- CRADD | c.573C>G p.P191= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV60555941; called by muse, mutect2, varscan2
- DSP | c.1116G>A p.L372= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV65795124; called by muse, mutect2, varscan2
- EPS8L3 | c.915G>A p.L305= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV62610401; called by muse, mutect2, varscan2
- FATE1 | c.78G>T p.G26= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV64849280; called by muse, mutect2, varscan2
- GABRA3 | c.996G>T p.V332= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV64804099; called by muse, mutect2, varscan2
- GSPT2 | c.900T>A p.G300= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV61214968; called by muse, mutect2, varscan2
- HRH1 | c.816C>G p.V272= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV67955880; called by muse, mutect2
- IGF1R | c.2211G>A p.R737= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs746636778, COSV51359528; called by muse, mutect2, varscan2
- MUC16 | c.1932G>A p.T644= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs751583909, COSV67459134, COSV67468221; called by muse, mutect2, varscan2
- NAV1 | c.1260C>G p.L420= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- PCNX3 | c.1767G>A p.R589= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV63140102; called by muse, mutect2, varscan2
- PRSS22 | c.630T>C p.H210= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV50723573; called by muse, mutect2, varscan2
- SAMD7 | c.765C>G p.L255= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV59418329, COSV59420804; called by muse, mutect2, varscan2
- ST7L | c.174C>A p.I58= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV54146904; called by muse, mutect2, varscan2
- SVIL | c.3321A>G p.G1107= (on ENST00000355867 / NM_021738.3; = p.G681= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs752516607, COSV63447311; called by muse, mutect2, varscan2
- UNC13A | c.2967G>A p.P989= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs748376721, COSV53207465; called by muse, mutect2, varscan2
- ABCA12 | c.986-23C>T | Intron (SNP) | VAF 7/52 reads (13%) | catalogued as COSV55972592; called by muse, mutect2, varscan2
- MACF1 | c.15832-9404C>G | Intron (SNP) | VAF 3/39 reads (8%) | catalogued as COSV57121400; called by muse, mutect2
